Somatic mutation profile of tumor specimen C3L-00189-03 (aliquot CPT0081060010_1) from CPTAC case C3L-00189, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 68.3 years (24,958 days).
Specimen C3L-00189-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c78fcb87-29a2-466e-8e52-79ff5f7ca235.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00189-31 (Blood Derived Normal), aliquot CPT0081100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3755917-0cc3-4098-8631-07683a59d7e7

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, 5'UTR 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 44/636 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- COL4A4 | c.4291C>T p.R1431C | Missense Mutation (SNP) | VAF 48/902 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.471); catalogued as rs536570392, COSV61631223; called by muse, mutect2
- LCT | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 26/520 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1447178344, COSV104384170, COSV99928573; called by muse, mutect2
- OTUD6A | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 29/608 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57974035; called by muse, mutect2
- SNX25 | c.527A>G p.Y176C | Missense Mutation (SNP) | VAF 32/584 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1265568494; called by muse, mutect2
- STXBP5 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 22/436 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99468674; called by muse, mutect2
- VAV1 | c.2393G>A p.R798Q | Missense Mutation (SNP) | VAF 20/446 reads (4%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.878); catalogued as COSV58380962, COSV58382256; called by muse, mutect2
- ARHGEF11 | c.2257C>T p.L753F | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARMC4 | c.703T>A p.C235S | Missense Mutation (SNP) | VAF 9/231 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2
- CCDC186 | c.1490A>C p.E497A | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CRELD1 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 18/484 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- CRYBB3 | c.206T>G p.F69C | Missense Mutation (SNP) | VAF 23/576 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GBX1 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 15/478 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, mutect2
- PLA2G1B | c.37G>C p.A13P | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.133); called by muse, mutect2
- SH3KBP1 | c.1605G>C p.K535N | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.086); called by muse, mutect2
- TGM6 | c.1817A>G p.D606G | Missense Mutation (SNP) | VAF 20/698 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.092); called by muse, mutect2
- SLC9A7 | c.1995C>T p.Y665= | Silent (SNP) | VAF 31/1022 reads (3%) | catalogued as rs1444255492, COSV100092100; called by muse, mutect2
- IGSF1 | c.-206C>T | 5'UTR (SNP) | VAF 13/270 reads (5%) | called by muse, mutect2
- PLK3 | c.-60C>T | 5'UTR (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
